Somatic mutation profile of tumor specimen TCGA-QH-A6X8-01A (aliquot TCGA-QH-A6X8-01A-12D-A32B-08) from TCGA case TCGA-QH-A6X8, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 56.9 years (20,771 days).
Specimen TCGA-QH-A6X8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8195ee0-dc9b-4e06-b4b1-85c9e6d1f232.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6X8-10B (Blood Derived Normal), aliquot TCGA-QH-A6X8-10B-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b09f6be-076c-4e4c-a6f5-47bca86735a4

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 11, Splice Site 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99360437; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MYH7 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148808089, CM066924; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1392_1403del p.D464_Y467del (on ENST00000521381 / NM_181523.3; = p.D194_Y197del on NM_181504.4) | In Frame Del (DEL) | VAF 11/33 reads (33%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACSM5 | c.1580A>C p.H527P | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV100089699; called by muse, mutect2, varscan2
- BLK | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs775270203, COSV99377768; called by muse, mutect2, varscan2
- CALN1 | c.644G>A p.R215Q (on ENST00000329008 / NM_001017440.3; = p.R257Q on NM_031468.4) | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs370771019, COSV61142530; called by muse, mutect2, varscan2
- CCND1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs913470506, COSV99919929; called by muse, mutect2, varscan2
- COL12A1 | c.613G>C p.A205P | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.303); catalogued as COSV100486778; called by muse, mutect2, varscan2
- DACH2 | c.1639C>G p.L547V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV100914087, COSV64179616; called by muse, mutect2, varscan2
- DNAH8 | c.10514G>C p.S3505T | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV100547443; called by muse, mutect2
- GLRA2 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as COSV99491735; called by muse, mutect2, varscan2
- HSPG2 | c.8317-1G>A p.X2773_splice | Splice Site (SNP) | VAF 8/14 reads (57%) | catalogued as COSV101021401; called by muse, mutect2, varscan2
- KRT73 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.726); catalogued as COSV99988931; called by muse, mutect2, varscan2
- MAGEB6 | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100983895; called by muse, mutect2, varscan2
- MYH1 | c.5533C>T p.R1845C | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1039075314, COSV56843263; called by muse, mutect2, varscan2
- NBN | c.1289A>G p.Q430R | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1563531531, COSV99620263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEURL4 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs752284717, COSV100224867; called by mutect2, varscan2
- NT5C1B | c.1071G>T p.K357N (on ENST00000359846 / NM_001199086.2; = p.K297N on NM_033253.4) | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100410342; called by muse, mutect2, varscan2
- PCDHB1 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 5/127 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs781938927; called by muse, mutect2
- PIK3C2A | c.1897+1G>A p.X633_splice | Splice Site (SNP) | VAF 117/150 reads (78%) | catalogued as COSV99791393; called by muse, mutect2, varscan2
- RADX | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs775530156, COSV65319126; called by muse, mutect2, varscan2
- TIGIT | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs376892258, COSV67328921; called by muse, mutect2
- UBN2 | c.3071C>T p.T1024M | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs200304697, COSV56036712; called by muse, mutect2, varscan2
- BCAS3 | c.1197T>C p.L399= | Silent (SNP) | VAF 68/178 reads (38%) | catalogued as COSV101177418; called by muse, mutect2, varscan2
- FAM83B | c.2094G>A p.K698= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV60919326, COSV60925211; called by muse, mutect2, varscan2
- IGSF1 | c.1780C>T p.L594= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as COSV100812323; called by muse, mutect2, varscan2
- KDELR2 | c.582C>T p.F194= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV99330762; called by muse, mutect2, varscan2
- KIF18B | c.2466T>C p.S822= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs760039387, COSV100192702; called by muse, varscan2
- LONRF3 | c.2199C>G p.P733= (on ENST00000371628 / NM_001031855.3; = p.P692= on NM_024778.5) | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as COSV100504754; called by muse, mutect2, varscan2
- MUC16 | c.28956C>T p.P9652= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs936143455, COSV101202131; called by muse, mutect2, varscan2
- NCAPD3 | c.2424A>G p.A808= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV101599408; called by muse, mutect2, varscan2
- PDK3 | c.1209A>G p.K403= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100998222; called by muse, mutect2, varscan2
- PLXNA1 | c.849G>A p.V283= | Silent (SNP) | VAF 13/229 reads (6%) | catalogued as COSV99304342; called by muse, mutect2
- SPATA17 | c.453C>T p.L151= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs1051633224, COSV100861213; called by muse, mutect2, varscan2
- SPIN4 | c.-1T>A | 5'UTR (SNP) | VAF 23/69 reads (33%) | catalogued as COSV100633431; called by muse, mutect2, varscan2
